Somatic mutation profile of tumor specimen TARGET-10-PARVBY-09A (aliquot TARGET-10-PARVBY-09A-01D) from TARGET case TARGET-10-PARVBY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (970 days).
Specimen TARGET-10-PARVBY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26c20748-3dac-40fa-8d72-1ece2aad339a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARVBY-10A (Blood Derived Normal), aliquot TARGET-10-PARVBY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/260d0acd-63a4-47e1-ad69-d0e15b759673

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 15/31 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.3347G>A p.R1116H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs761846748, COSV99176829, COSV99179180; called by muse, mutect2, varscan2
- SVIL | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs138346979; called by muse, mutect2, varscan2
- VEGFC | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs764367424; called by muse, mutect2, varscan2
- CYP4X1 | c.1095G>A p.S365= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs368977020; called by muse, mutect2, varscan2
- EPB41L4A | c.1017G>T p.R339= | Silent (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
